CCDI case PBCLKL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/7b39408f-9b1c-49ae-9ff4-25107d62cf44

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Schwannoma, NOS: ICD-O-3 morphology code: 9560/0; Tissue or organ of origin: Spinal cord; Age at diagnosis: 17.9 years (6,527 days).

Biospecimens (3 samples)
- Sample 0DUIWU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUIX3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUIXR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
